Gene-level copy-number profile of tumor specimen C3N-01765-01 from CPTAC case C3N-01765, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.3 years (21,285 days).
Specimen C3N-01765-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b7fb247b-86a0-4370-ae1e-c8cb382aa87e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01765-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/484521c9-0631-43b7-acb7-5f8b8ddbdb06

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3; copy number 3: 79; copy number 4: 58,178; copy number 5: 146.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
